Somatic mutation profile of tumor specimen TARGET-20-PASEGC-09A (aliquot TARGET-20-PASEGC-09A-01D) from TARGET case TARGET-20-PASEGC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.8 years (4,312 days).
Specimen TARGET-20-PASEGC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3222a1ee-1dd9-478d-98d2-4a6d694d62e1.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASEGC-14A (Bone Marrow Normal), aliquot TARGET-20-PASEGC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d66b7ec-f5c9-4321-abaf-4b902b3d8d67

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 59/155 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.863_864insTTTG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 21/40 reads (53%) | catalogued as COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- SIN3A | c.974A>G p.Y325C | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760260844, COSV64582527; called by muse, mutect2, varscan2
